Somatic mutation profile of tumor specimen C3L-02953-01 (aliquot CPT0161590011) from CPTAC case C3L-02953, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.8 years (20,752 days).
Specimen C3L-02953-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cdf9d4c-cdb4-4187-9ebd-cbe7522f1031.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02953-31 (Blood Derived Normal), aliquot CPT0162520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84192b2d-5953-4d61-9ae1-c31bb5d5b411

The open-access MAF lists 83 somatic variants for this specimen: 48 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 24, Intron 6, 5'UTR 4, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2B | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs776754289, COSV61701092; called by muse, mutect2, varscan2
- ANKFY1 | c.2237G>A p.R746H (on ENST00000341657 / NM_001330063.2; = p.R747H on NM_016376.5) | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs762073269, COSV58918602, COSV58920120; called by muse, mutect2
- ARID1A | c.6260G>T p.G2087V | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253928, COSV61375511; called by muse, mutect2, varscan2
- DOT1L | c.3826C>T p.R1276W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs759369415, COSV67111780; called by muse, mutect2, varscan2
- ELFN2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749342938; called by muse, mutect2, varscan2
- FBN3 | c.6871G>A p.E2291K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs564631372; called by muse, mutect2, varscan2
- HERC2 | c.7532C>T p.T2511M | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs141913704; called by muse, mutect2, varscan2
- ITIH5 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs199952014, COSV53660667; called by muse, mutect2, varscan2
- KCNV1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749043466, COSV52088536, COSV99819118; called by muse, mutect2, varscan2
- KMT2C | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51285736; called by muse, mutect2
- MGAT5B | c.1502G>A p.R501Q (on ENST00000569840 / NM_001199172.2; = p.R499Q on NM_144677.3) | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs367973248; called by muse, mutect2, varscan2
- MPST | c.334C>T p.R112C (on ENST00000341116 / NM_001369904.2; = p.R132C on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902980493; called by muse, mutect2, varscan2
- NES | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs551525830; called by muse, mutect2, varscan2
- NUMB | c.1427C>G p.S476C (on ENST00000355058; = p.S465C on NM_003744.5) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV99390456; called by muse, mutect2, varscan2
- PDE9A | c.810+1G>T p.X270_splice | Splice Site (SNP) | VAF 34/148 reads (23%) | catalogued as COSV52323459; called by muse, mutect2, varscan2
- PTPRU | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs1217637863, COSV60530790; called by muse, mutect2, varscan2
- RFX6 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1416048424; called by muse, mutect2, varscan2
- RREB1 | c.3944C>T p.T1315M | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375377458; called by muse, mutect2, varscan2
- SFI1 | c.2527C>T p.R843W (on ENST00000400288 / NM_001007467.3; = p.R812W on NM_014775.4) | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs367957589; called by muse, mutect2, varscan2
- SLC28A3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as rs960470501; called by muse, mutect2, varscan2
- SLC9C1 | c.2145A>T p.Q715H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV99997051; called by muse, mutect2
- SYK | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201857010, COSV65325628; called by muse, mutect2, varscan2
- TBX5 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as CM1312924, COSV100092453; called by muse, mutect2
- UNC13C | c.6127G>A p.V2043M | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as rs746140625, COSV52897447; called by muse, mutect2, varscan2
- UROD | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs763913128, CM024485; called by muse, mutect2, varscan2
- ZBTB2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs867911053; called by muse, mutect2, varscan2
- CCDC148 | c.5G>A p.C2Y | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDAH1 | c.848T>G p.V283G | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- DTYMK | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- EXOC8 | c.1907T>A p.F636Y | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GTDC1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 26/124 reads (21%) | called by muse, mutect2, varscan2
- KIF20A | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- KMT2D | c.7718G>T p.G2573V | Missense Mutation (SNP) | VAF 94/424 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- LIN7C | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR4K5 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH15 | c.4410C>A p.N1470K | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R1 | c.1327_1356del p.E443_Y452del (on ENST00000521381 / NM_181523.3; = p.E173_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- PTEN | c.878dup p.S294Kfs*4 | Frame Shift Ins (INS) | VAF 158/378 reads (42%) | called by mutect2, pindel, varscan2
- PTPRS | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SIGLEC5 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SLC9A3R2 | c.283del p.E95Sfs*7 | Frame Shift Del (DEL) | VAF 148/539 reads (27%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- STK26 | c.1065G>C p.M355I | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SUGP2 | c.2954A>G p.Y985C | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TCF20 | c.3805C>G p.Q1269E | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TEKT4 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 61/210 reads (29%) | called by muse, mutect2, varscan2
- TNFRSF10A | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZC3H7B | c.1756T>C p.Y586H | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- BLK | c.900C>T p.Y300= | Silent (SNP) | VAF 50/147 reads (34%) | catalogued as rs139994406; called by muse, mutect2, varscan2
- CAMLG | c.750G>A p.S250= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs1460187266, COSV51804740; called by muse, mutect2, varscan2
- CCDC159 | c.375C>T p.A125= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs1197700433; called by muse, mutect2, varscan2
- CDC42BPG | c.555G>A p.S185= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs559752796; called by muse, mutect2, varscan2
- CSMD2 | c.5445G>A p.P1815= | Silent (SNP) | VAF 75/170 reads (44%) | catalogued as rs548355797, COSV53945590; called by muse, mutect2, varscan2
- DSEL | c.1771C>T p.L591= | Silent (SNP) | VAF 47/238 reads (20%) | catalogued as rs371822639; called by muse, mutect2, varscan2
- GLT6D1 | c.417C>T p.T139= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs371852008; called by muse, mutect2, varscan2
- HCN1 | c.120C>A p.G40= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- HEMGN | c.315G>A p.E105= | Silent (SNP) | VAF 86/297 reads (29%) | called by muse, mutect2, varscan2
- IKZF1 | c.879C>T p.Y293= | Silent (SNP) | VAF 64/226 reads (28%) | catalogued as rs1449573722, COSV100498111; called by muse, varscan2
- KCNH5 | c.2103C>T p.P701= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as rs112731796, COSV59770233; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2D | c.7719C>T p.G2573= | Silent (SNP) | VAF 94/426 reads (22%) | called by muse, mutect2, varscan2
- MYO16 | c.4014C>T p.D1338= | Silent (SNP) | VAF 74/297 reads (25%) | catalogued as COSV62759633; called by muse, mutect2, varscan2
- PAX6 | c.117G>A p.P39= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs919486001, CD001003; called by muse, mutect2
- PCDHA3 | c.1776G>A p.A592= | Silent (SNP) | VAF 143/529 reads (27%) | catalogued as rs1233105418, COSV63540344; called by muse, mutect2, varscan2
- PLP2 | c.336C>T p.I112= | Silent (SNP) | VAF 131/424 reads (31%) | catalogued as rs376504002; called by muse, mutect2, varscan2
- PXDNL | c.2586C>T p.F862= | Silent (SNP) | VAF 63/256 reads (25%) | catalogued as rs754744909, COSV62493734; called by muse, mutect2, varscan2
- RNASEH2A | c.285G>C p.V95= | Silent (SNP) | VAF 153/604 reads (25%) | called by muse, mutect2, varscan2
- TBC1D15 | c.798C>G p.P266= | Silent (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- TERT | c.2733C>T p.D911= | Silent (SNP) | VAF 19/409 reads (5%) | catalogued as rs768646695, COSV57204613; ClinVar: likely benign; called by muse, mutect2
- TMEM121 | c.72C>T p.V24= | Silent (SNP) | VAF 75/277 reads (27%) | called by muse, mutect2, varscan2
- UBE3C | c.255T>A p.A85= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- USP3 | c.561C>T p.F187= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- ZNF687 | c.1770C>T p.L590= | Silent (SNP) | VAF 56/584 reads (10%) | catalogued as rs770915268; called by muse, mutect2
- CAP2 | c.637-3017G>A | Intron (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- COL21A1 | c.2407+15T>C | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- EIF3E | c.91-316A>G | Intron (SNP) | VAF 52/355 reads (15%) | called by muse, mutect2, varscan2
- GLRX5 | chr14:95535044 del CCAGCTGTGGGC | 5'UTR (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- GPR107 | c.-23C>T | 5'UTR (SNP) | VAF 47/213 reads (22%) | catalogued as rs1410643124; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2545G>A | Intron (SNP) | VAF 91/506 reads (18%) | catalogued as rs1458179483; called by muse, mutect2, varscan2
- PPP1CB | c.-67C>T | 5'UTR (SNP) | VAF 99/328 reads (30%) | catalogued as COSV56092052; called by muse, mutect2, varscan2
- SHF | c.-96_-94del | 5'UTR (DEL) | VAF 44/198 reads (22%) | called by pindel, varscan2
- TMEM184A | c.645-256C>T | Intron (SNP) | VAF 41/177 reads (23%) | catalogued as rs760790723; called by muse, mutect2, varscan2
- UNC13C | c.4933+1891T>A | Intron (SNP) | VAF 71/274 reads (26%) | called by muse, mutect2, varscan2
- ZBTB8OS | c.*44T>C | 3'UTR (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
